Gene-level copy-number profile of tumor specimen TCGA-02-0001-01C from TCGA case TCGA-02-0001, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.3 years (16,179 days).
Specimen TCGA-02-0001-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.86675433-1ee1-448b-901a-aa906722a510.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0001-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94274990-563c-4f1e-a661-eca8a9f77178

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 9,052; copy number 2: 27,548; copy number 3: 19,397; copy number 4: 797; copy number 5: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0001-01): tumor purity 0.49, ploidy 3.47, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,214,672, 10 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,014 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,631. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
